Somatic mutation profile of tumor specimen TCGA-2L-AAQA-01A (aliquot TCGA-2L-AAQA-01A-21D-A38G-08) from TCGA case TCGA-2L-AAQA, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 76.9 years (28,074 days).
Specimen TCGA-2L-AAQA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe4c8b59-c354-4cb0-881f-c5a018e5ff49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2L-AAQA-11A (Solid Tissue Normal), aliquot TCGA-2L-AAQA-11A-11D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea163607-2c05-473d-ad33-fe1a804ef7d5

The open-access MAF lists 64 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 14, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2, RNA 1, In Frame Del 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 115/376 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1616C>G p.P539R | Missense Mutation (SNP) | VAF 97/373 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs121913285, COSV104381411, COSV55876380; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 150/324 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AGL | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 79/231 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs764208593, COSV99649200; called by muse, mutect2, varscan2
- ALPK2 | c.1464T>A p.D488E | Missense Mutation (SNP) | VAF 169/392 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.052); catalogued as COSV100864389; called by muse, mutect2, varscan2
- ASTN1 | c.3769G>A p.E1257K | Missense Mutation (SNP) | VAF 99/726 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as rs538221544, COSV62495987; called by muse, mutect2, varscan2
- CBLL1 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 138/458 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.755); catalogued as rs768405085, COSV56029910, COSV99755655; called by muse, mutect2, varscan2
- CCL8 | c.195C>T p.I65= | Splice Region (SNP) | VAF 45/130 reads (35%) | catalogued as rs1398790624, COSV101126430; called by muse, mutect2, varscan2
- CDH2 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 162/359 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs201148355, COSV52293905; called by muse, mutect2, varscan2
- COL24A1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 131/326 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs765914443, COSV100992832, COSV65303101; called by muse, mutect2, varscan2
- CPNE8 | c.871T>A p.L291M | Missense Mutation (SNP) | VAF 150/578 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as COSV100504352; called by muse, mutect2, varscan2
- CRTAC1 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 66/285 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs774938607, COSV53997672; called by muse, mutect2, varscan2
- CTNND2 | c.3434T>G p.V1145G | Missense Mutation (SNP) | VAF 97/323 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV100476472; called by muse, mutect2, varscan2
- DND1 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 95/461 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.048); catalogued as COSV100298033, COSV56907901; called by muse, mutect2, varscan2
- DSCAM | c.5822C>T p.T1941M | Missense Mutation (SNP) | VAF 93/311 reads (30%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.23); catalogued as rs780214745, COSV68040142; called by muse, mutect2, varscan2
- GPR156 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 121/406 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100251370; called by muse, mutect2, varscan2
- GPSM1 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140085951, COSV100696617; called by muse, mutect2, varscan2
- HIPK3 | c.2316G>C p.L772F | Missense Mutation (SNP) | VAF 77/222 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.157); catalogued as COSV100305781; called by muse, mutect2, varscan2
- HK3 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 107/386 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs776797141, COSV52842032; called by muse, mutect2, varscan2
- INHBB | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 123/430 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs746505306, COSV54677282; called by muse, mutect2, varscan2
- ITGA6 | c.514T>A p.W172R | Missense Mutation (SNP) | VAF 243/808 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99905524; called by muse, mutect2, varscan2
- ITPR1 | c.3043G>A p.G1015R (on ENST00000354582; = p.G1000R on NM_002222.7) | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as rs1020207172, COSV56994263; called by muse, mutect2, varscan2
- MAGEL2 | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 22/277 reads (8%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.006); catalogued as COSV100045932; called by muse, mutect2
- MUC6 | c.6387_6389del p.S2130del | In Frame Del (DEL) | VAF 57/201 reads (28%) | catalogued as rs765184193; called by pindel, varscan2
- MYO1F | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 21/736 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs1171244907, COSV100596697; called by muse, mutect2
- NCKAP5L | c.568A>T p.I190F | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100258818; called by muse, mutect2, varscan2
- OR2Y1 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 80/230 reads (35%) | catalogued as rs372667309; called by muse, mutect2, varscan2
- PAMR1 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 329/1151 reads (29%) | catalogued as rs368867348; called by muse, mutect2, varscan2
- PCNA | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.472); catalogued as COSV100996241; called by muse, mutect2
- PDCD2L | c.802T>C p.S268P | Missense Mutation (SNP) | VAF 379/1247 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99874993; called by muse, mutect2, varscan2
- PEX16 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 129/482 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV99572213; called by muse, mutect2, varscan2
- PMEPA1 | c.624del p.S209Afs*61 | Frame Shift Del (DEL) | VAF 62/274 reads (23%) | catalogued as rs751873496; called by mutect2, pindel, varscan2
- PPM1G | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 17/416 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs920134901, COSV100085131; called by muse, mutect2
- RAB40B | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 81/241 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs750727711, COSV99483673; called by muse, mutect2, varscan2
- RASAL3 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs756653570, COSV100640296; called by muse, mutect2, varscan2
- SGCD | c.28C>T p.R10W (on ENST00000435422 / NM_001128209.2; = p.R11W on NM_000337.5) | Missense Mutation (SNP) | VAF 95/352 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs566181541, COSV61911651; called by muse, mutect2, varscan2
- SLF2 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.919); catalogued as rs753643824, COSV99489188; called by muse, mutect2, varscan2
- SPDYE1 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1562630386, COSV99323977; called by muse, mutect2, varscan2
- SRFBP1 | c.1226G>A p.R409K | Missense Mutation (SNP) | VAF 139/384 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as COSV100232749; called by muse, mutect2, varscan2
- TNPO1 | c.2414G>A p.W805* | Nonsense Mutation (SNP) | VAF 176/565 reads (31%) | catalogued as COSV61523299, COSV61523689; called by muse, mutect2, varscan2
- TONSL | c.3006+1G>A p.X1002_splice | Splice Site (SNP) | VAF 37/127 reads (29%) | catalogued as rs1410421395, COSV101340243; called by muse, mutect2, varscan2
- TRIOBP | c.5789G>A p.R1930Q (on ENST00000644935 / NM_001039141.3; = p.R217Q on NM_007032.5) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as rs755965685, COSV100462293; called by muse, varscan2
- TRIOBP | c.6829C>T p.R2277W (on ENST00000644935 / NM_001039141.3; = p.R564W on NM_007032.5) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs765348097, COSV100730855; called by muse, varscan2
- UXS1 | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99308239; called by muse, mutect2, varscan2
- ZNF3 | c.599A>G p.H200R | Missense Mutation (SNP) | VAF 157/544 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs759319469, COSV99447242; called by muse, mutect2, varscan2
- ZNF787 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1258426239, COSV99555542; called by muse, mutect2, varscan2
- ARRDC1 | c.119-8_125del p.X40_splice | Splice Site (DEL) | VAF 37/155 reads (24%) | called by mutect2, pindel, varscan2
- RNF43 | c.31_35del p.A11Lfs*27 | Frame Shift Del (DEL) | VAF 34/159 reads (21%) | called by pindel, varscan2
- AP4B1 | c.225T>C p.Y75= | Silent (SNP) | VAF 142/303 reads (47%) | catalogued as rs748056404, COSV99870794; called by muse, mutect2, varscan2
- EXOC7 | c.201G>A p.T67= | Silent (SNP) | VAF 110/239 reads (46%) | catalogued as rs763681538, COSV100135265; called by muse, mutect2, varscan2
- FANCD2 | c.2343C>T p.F781= | Silent (SNP) | VAF 69/304 reads (23%) | catalogued as COSV99811255; called by muse, mutect2, varscan2
- FAT2 | c.12588C>T p.S4196= | Silent (SNP) | VAF 171/609 reads (28%) | catalogued as rs1326960576, COSV55817811; called by muse, mutect2, varscan2
- ISLR2 | c.753C>T p.R251= | Silent (SNP) | VAF 94/302 reads (31%) | catalogued as COSV62301756; called by muse, mutect2, varscan2
- KCNA6 | c.804G>A p.T268= | Silent (SNP) | VAF 146/483 reads (30%) | catalogued as COSV54974980; called by muse, mutect2, varscan2
- KIF24 | c.2844T>C p.Y948= | Silent (SNP) | VAF 141/464 reads (30%) | catalogued as rs1360517814, COSV99903183; called by muse, mutect2, varscan2
- PCDHGA5 | c.1722C>T p.G574= | Silent (SNP) | VAF 314/956 reads (33%) | catalogued as COSV54014702; called by muse, mutect2, varscan2
- PHF1 | c.867C>A p.L289= | Silent (SNP) | VAF 146/420 reads (35%) | catalogued as COSV100992623; called by muse, mutect2, varscan2
- PRADC1 | c.126C>T p.Y42= | Silent (SNP) | VAF 68/265 reads (26%) | catalogued as rs1344884046, COSV99240239; called by muse, mutect2, varscan2
- SBK2 | c.369C>T p.Y123= | Silent (SNP) | VAF 60/207 reads (29%) | catalogued as rs200066533, COSV60013308; called by muse, mutect2, varscan2
- SKOR1 | c.1590C>T p.S530= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as rs1415570554, COSV100408346; called by muse, mutect2
- TRIB2 | c.177T>G p.S59= | Silent (SNP) | VAF 157/557 reads (28%) | catalogued as COSV99331100; called by muse, mutect2, varscan2
- TSHZ2 | c.1830G>A p.A610= | Silent (SNP) | VAF 141/553 reads (25%) | catalogued as rs147016688, COSV61587419; called by muse, mutect2, varscan2
- CSNK1G2 | c.-266+12444G>A | Intron (SNP) | VAF 97/336 reads (29%) | catalogued as rs769179876, COSV99729907; called by muse, mutect2, varscan2
- FRMPD2B | n.926C>T | RNA (SNP) | VAF 246/1813 reads (14%) | catalogued as rs1280331889; called by muse, mutect2, varscan2
